TCGA case TCGA-RP-A6K9 — Skin Cutaneous Melanoma (TCGA-SKCM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Bones, joints and articular cartilage of other and unspecified sites; Tissue source site: St. Joseph's Hospital AZ. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5359d381-e7f2-4155-a559-7da9cda42ed9

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Vital status: Alive.

Diagnoses (3)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C41.0; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Bones of skull and face and associated joints; Classification of tumor: metastasis; Prior treatment: Yes.
   Treatment given: Treatment type: Chemotherapy; Timepoint category: Prior to Procurement.
   Recorded as not given: Radiation Therapy, NOS, prior to procurement.
2. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Year of diagnosis: 2001; AJCC staging edition: 5th; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Melanoma known primary: Yes.
   Pathology details: Consistent pathology review: Yes.
3. Malignant melanoma, NOS: Tissue or organ of origin: Skin, NOS; Classification of tumor: primary.
   Recorded as not given: Radiation Therapy, NOS.

Follow-up (1 entry)
- Follow-up contact recording only the day: follow-up.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 48 kg; Height: 162 cm; BMI: 18.3.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-RP-A6K9-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-RP-A6K9-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT; Initial weight: 560 mg.
  Slide TCGA-RP-A6K9-06A-04-TS4: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 20; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-RP-A6K9-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Radiation therapy to primary: No; Primary location: Distant Metastasis; Metastatic tumor site: posterior skull; Primary melanoma skin type: Non-glabrous skin; Prior radiation therapy: No; History neoadjuvant treatment: Yes.
- Follow-up form: Lost to follow-up: Yes.

GDC annotations on this case (curator notes; quoted as recorded):
- Neoadjuvant therapy: During Enrollment it was found that patient received chemotherapy and IFN prior to TCGA tumor procurement.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), time not recorded; disease-specific survival: no event (censored), time not recorded; progression-free interval: no event (censored), time not recorded.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-RP-A6K9-06A-41D-A34T-01): tumor purity 0.47, ploidy 3.58, whole-genome doublings 1.
